TCGA case TCGA-K4-AAQO — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: ABS - Lahey Clinic. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/383bf27a-9216-492e-b4bd-2b4eef8278de

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.3; Tissue or organ of origin: Anterior wall of bladder; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 56.6 years (20,683 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC clinical T: T3; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes; Days to last follow up: 359 days.
   Pathology details: Consistent pathology review: Yes; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin + Gemcitabine; Days to treatment start: 120 days; Days to treatment end: 181 days; Treatment outcome: Partial Response.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 359.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 100 kg; Height: 180 cm; BMI: 30.9.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 43; Tobacco smoking quit year: 2013; Age at onset: 15.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-K4-AAQO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 660 mg.
  Slide TCGA-K4-AAQO-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-K4-AAQO-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-K4-AAQO-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: Yes; Tobacco smoking history indicator: 4; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Wall Anterior; Lymphovascular invasion: Yes; Incidental prostate cancer indicator: No.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome at TCGA followup: Stable Disease.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Patient received neoadjuvant chemotherapy (gemcitabine and cisplatin).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 359 days; disease-specific survival: no event (censored), 359 days; progression-free interval: no event (censored), 359 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-K4-AAQO-01A-11D-A38F-01): tumor purity 0.33, ploidy 3.08, whole-genome doublings 1.
